Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A3L3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A3L3-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVIEW

Case Number :

Diagnosis:

A: Uterus, cervix, bilateral tubes and ovaries, total hysterectomy and bilateral salpingo-oophorectomy

Uterus and cervix, hysterectomy:

Location of tumor: primary endometrial cancer

Histologic type: serous adenocarcinoma

Comment: Immunohistochemistry performed on the prior endometrial curettage

, demonstrated diffuse staining of the tumor for P53 and P16, further supporting an interpretation of serous adenocarcinoma.

Histologic grade (FIGO): high grade 3

Extent of invasion: see below

Myometrial invasion: Inner half
Depth: 7 mm Wall thickness: 28 mm
Percent: 28% (A9, A10)

1CD-0-3
adenocarcinoma, serous, Nos 8380/3
Site: Endometrium C54.1
WJ
12/19/11

Serosal involvement: not identified

Lower uterine segment involvement: present

Cervical involvement: not identified

Adnexal involvement (see below): not identified

Other sites: not identified

Cervical/vaginal margin and distance: negative, widely free

Lymphovascular space invasion: not identified in the sections examined

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 17

[page 2 of 5]
Other pathologic findings: adenomyosis

Tumor estrogen receptor and progesterone receptor
immunohistochemistry

results: pending on block A9, addendum to follow

AJCC Pathologic Stage: pT1a pN0

FIGO (2008 classification) Stage grouping: IA, grade 3

These stages are based on information available at the time of
this report, and
are subject to change pending additional information and
clinical review.

Ovary, right, oophorectomy:

- No tumor identified

Ovary, left, oophorectomy:

- No tumor identified

Fallopian tube, right, salpingectomy:

- No tumor identified

Fallopian tube, left, salpingectomy:

- No tumor identified

B: Lymph node, right periaortic, excision

- No tumor identified in one lymph node (0/1)

C: Lymph nodes, left periaortic, excision

- No tumor identified in two lymph nodes (0/2)

D: Lymph nodes, right pelvic, excision

- No tumor identified in six lymph nodes (0/6)

E: Lymph nodes, left pelvic, excision

- No tumor identified in eight lymph nodes (0/8)

Clinical History:

-year-old female with endometrial cancer.

Gross Description:

[page 3 of 5]
Specimen A is received in one appropriately labeled container.

Adnexa: Bilateral tubes and ovaries present

Weight: 295 grams

Shape: Pear shaped

Dimensions:

height: 13.2 cm

anterior to posterior width: 5.4 cm

breadth at fundus: 7.8 cm

Serosa: The serosal surface is tan/pink, smooth and glistening.

Cervix: 2.5 x 2.4 x 1.9 cm

length of endocervical canal:

ectocervix: Tan/pink smooth and glistening with areas of cautery present

endocervix: Tan/white and trabeculated

Endomyometrium:

length of endometrial cavity: 5.2 cm

width of endometrial cavity at fundus: 5.3 cm

tumor findings:

dimensions: 4.8 x 4.5 x 3.1 cm

appearance: The tumor is tan/white and exophytic/fungating in appearance

location and extent: The tumor involves both the anterior and posterior endometrium and grossly appears to involve the anterior lower uterine segment.

myometrial invasion: Inner one-half

thickness of myometrial wall at deepest gross invasion: 2.8 cm

other findings or comments: None

Adnexa:

Right ovary:

dimensions: 2.0 x 1.1 x 0.3 cm

external surface: Tan/white and cerebriform

cut surface: Tan/white and unremarkable

Right fallopian tube:

dimensions: 4.8 cm in length and 0.6 cm in diameter

other findings: Sectioning reveals a patent lumen

Left ovary:

dimensions: 2.1 cm x 0.8 x 0.3 cm

external surface: Tan/white and cerebriform

cut surface: Tan/white and unremarkable

Left fallopian tube:

dimensions: 3.4 cm in length and 0.6 cm in diameter

other findings: Sectioning reveals a patent lumen

Lymph nodes: N/A

[page 4 of 5]
Other comments: Tumor given to tissue procurement.

Digital photograph taken: No

Block Summary:

- A1 - Anterior cervix
- A2 - Anterior lower uterine segment
- A3-A4 - Anterior mid corpus, bisected
- A5 - Anterior upper corpus
- A6 - Anterior lower corpus
- A7 - Posterior cervix
- A8 - Posterior lower uterine segment
- A9-A10 - Posterior mid corpus, bisected
- A11-A12 - Posterior upper corpus, bisected
- A13 - Right ovary and right fallopian tube
- A14 - Left ovary and left fallopian tube

Container B is additionally labeled "right periaortic nodes" and is an aggregate of yellow/tan fibrofatty tissue measuring 4.1 x 2.2 x 0.4 cm. The tissue is dissected for lymph node candidates and two lymph node candidates are identified ranging in largest diameter from 1.2 to 2.8 cm.

Block Summary:

- B1 - One lymph node candidate
- B2 - One lymph node candidate
- B3 - Remaining tissue,

Container C is additionally labeled "left periaortic nodes" and is an aggregate of yellow/tan fibrofatty tissue measuring 2.2 x 1.5 x 0.3 cm. The tissue is dissected for lymph node candidates and one lymph node candidate is identified with a diameter of 1.4 cm.

Block Summary:

- C1 - One lymph node candidate
- C2 - Remaining tissue,

Container D is additionally labeled "right pelvic nodes" and is an aggregate of yellow/tan fibrofatty tissue measuring 4.8 x 4.2 x 0.9 cm. The

[page 5 of 5]
tissue is
dissected for lymph node candidates and five lymph node
candidates are
identified ranging in largest diameter from 0.7 to 4.5 cm.

Block Summary:

- D1 - Three lymph node candidates
- D2 - One lymph node candidate, bisected
- D3-D4 - Representative sections of largest lymph node candidate
- D5-D6 - Remaining tissue

Container E is additionally labeled "left pelvic nodes" and is
an aggregate of
yellow/tan fibrofatty tissue measuring 5.8 x 4.5 x 1.0 cm. The
tissue is
dissected for lymph node candidates and seven lymph node
candidates are
identified ranging in largest diameter from 0.8 to 2.7 cm.

Block Summary:

- E1 - Three lymph node candidates
- E2 - One lymph node candidate, bisected
- E3 - One lymph node candidate
- E4 - One lymph node candidate
- E5 - One lymph node candidate
- E6 - Remaining tissue

Source: NCI Genomic Data Commons file 67b27e5b-f101-4e62-b1a7-55e52a2c1637 (TCGA-EY-A3L3.DBCC8E6F-3AB9-41B2-8266-341509A9FDB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).